Somatic mutation profile of tumor specimen TCGA-KU-A6H7-01A (aliquot TCGA-KU-A6H7-01A-11D-A31L-08) from TCGA case TCGA-KU-A6H7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 55.6 years (20,314 days).
Specimen TCGA-KU-A6H7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a708cdaf-b782-446d-ad63-8df852b3487f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KU-A6H7-10A (Blood Derived Normal), aliquot TCGA-KU-A6H7-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/664babd7-e47a-4ab8-9897-ca973274441b

The open-access MAF lists 148 somatic variants for this specimen: 114 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 31, Nonsense Mutation 10, Splice Site 4, Frame Shift Del 3, RNA 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | hotspot (GDC flag); catalogued as rs1131690863, CM941204, COSV57294817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100933104; called by muse, mutect2, varscan2
- ABCC2 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100966462; called by muse, mutect2, varscan2
- AFF1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV100320114; called by muse, mutect2, varscan2
- AFF1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 31/222 reads (14%) | catalogued as COSV100320404; called by muse, mutect2, varscan2
- AGO4 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs751364147, COSV64618677; called by muse, mutect2, varscan2
- ARID4A | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100794161; called by muse, mutect2, varscan2
- ATR | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100638048; called by muse, mutect2
- B3GNT8 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV99524536; called by muse, mutect2, varscan2
- BFSP2 | c.1247G>T p.*416Lext*17 | Nonstop Mutation (SNP) | VAF 13/134 reads (10%) | catalogued as COSV100183688; called by muse, mutect2, varscan2
- BOD1L1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99239054; called by muse, mutect2
- C3orf33 | c.400G>C p.E134Q (on ENST00000340171 / NM_001308229.2; = p.E91Q on NM_173657.2) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as rs765123303, COSV100420055; called by muse, mutect2, varscan2
- CACNA1H | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772154386, COSV61988665; called by muse, mutect2, varscan2
- CDC40 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV100309239; called by muse, mutect2, varscan2
- CDH11 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99217974, COSV99219293; called by muse, mutect2, varscan2
- CHD9 | c.8218G>A p.E2740K (on ENST00000398510 / NM_001382353.1; = p.E2724K on NM_025134.7) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.952); catalogued as rs908656757, COSV99529043; called by muse, mutect2, varscan2
- CIC | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs1236337069, COSV50562195, COSV99359387; called by muse, mutect2, varscan2
- CKAP2L | c.879G>C p.K293N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100198560, COSV56696949; called by muse, mutect2, varscan2
- DHX38 | c.2277G>C p.Q759H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV99194276; called by muse, mutect2, varscan2
- DNASE1L1 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV99185893; called by muse, mutect2, varscan2
- DPH3 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV99550887; called by muse, mutect2, varscan2
- EEA1 | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV100467460; called by muse, mutect2
- EFHC1 | c.1721C>G p.S574* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100931992; called by muse, mutect2
- FAM193A | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV100218951; called by muse, mutect2
- FARP1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 21/120 reads (18%) | catalogued as COSV100130363; called by muse, mutect2, varscan2
- FCGR2A | c.674C>T p.A225V (on ENST00000271450 / NM_001136219.3; = p.A224V on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs199502630, COSV54839792; called by muse, mutect2, varscan2
- FIG4 | c.2432C>A p.S811* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100019516; called by muse, mutect2, varscan2
- FOS | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746383613, COSV100338466; called by muse, mutect2, varscan2
- GRIA1 | c.1135-1G>A p.X379_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53593222; called by muse, mutect2, varscan2
- GRK7 | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99379758; called by muse, mutect2, varscan2
- HMGXB4 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99330041; called by muse, varscan2
- HNRNPD | c.351T>A p.F117L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.359); catalogued as COSV100002848; called by muse, mutect2, varscan2
- HNRNPR | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.528); catalogued as rs1374998251, COSV100164429; called by muse, mutect2, varscan2
- HSPB8 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99931201; called by muse, mutect2
- ILF2 | c.1133C>G p.P378R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.954); catalogued as COSV100721923; called by muse, mutect2, varscan2
- IMMT | c.1797C>G p.I599M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99606247; called by muse, mutect2
- IRAK1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as COSV57656225; called by muse, mutect2, varscan2
- ISY1 | c.541+1G>T p.X181_splice | Splice Site (SNP) | VAF 34/106 reads (32%) | catalogued as COSV99860730, COSV99860886; called by muse, mutect2, varscan2
- ITPA | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101200062; called by muse, mutect2, varscan2
- KCNH7 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs776350714, COSV59783186; called by muse, mutect2, varscan2
- KCNQ4 | c.792C>G p.N264K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100714307; called by muse, mutect2, varscan2
- KIF19 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374148526, COSV100739049; called by muse, mutect2, varscan2
- KNG1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs779764784, COSV53979073, COSV53979592; called by muse, mutect2, varscan2
- KRBA2 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV100497646; called by muse, mutect2, varscan2
- KRT14 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs773622623, COSV99390973; called by muse, mutect2, varscan2
- KRT14 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99390976; called by muse, mutect2
- LAMA3 | c.5158G>A p.E1720K (on ENST00000313654 / NM_198129.4; = p.E111K on NM_000227.6) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs747914534, COSV99334511; called by muse, mutect2, varscan2
- LFNG | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV67864403; called by mutect2, varscan2
- LRP5 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99591792; called by muse, mutect2, varscan2
- LRRC8D | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100487117, COSV100487189, COSV61578075; called by muse, mutect2, varscan2
- LRRIQ1 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV67813078; called by muse, mutect2
- LRRK2 | c.4372G>A p.D1458N | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100109849; called by muse, mutect2, varscan2
- LUC7L2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV99692967; called by muse, mutect2, varscan2
- LUZP4 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs782627471, COSV100904848; called by muse, mutect2, varscan2
- MED29 | c.285G>C p.L95F (on ENST00000615911; = p.L74F on NM_017592.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55393213, COSV99655936; called by muse, mutect2
- MEOX1 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV100233725, COSV59355773; called by muse, mutect2
- MIA3 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100719406; called by muse, mutect2
- MPDZ | c.4025G>C p.G1342A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.751); catalogued as COSV100056555; called by muse, mutect2
- MROH8 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV99457001; called by muse, mutect2, varscan2
- MTCL1 | c.5680-1G>A p.X1894_splice (on ENST00000306329 / NM_001378206.1; = p.X1575_splice on NM_015210.4) | Splice Site (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100094176; called by muse, mutect2, varscan2
- MTPN | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101262952; called by muse, mutect2
- NEBL | c.1715C>G p.S572C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV101009172, COSV65801333; called by muse, mutect2, varscan2
- NLRC5 | c.4925C>T p.S1642L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52653415; called by muse, mutect2, varscan2
- NRDC | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV100703303, COSV100703793; called by muse, mutect2, varscan2
- OR4D5 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs564572858, COSV58305578; called by muse, varscan2
- PCDHB4 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV99522050; called by muse, mutect2
- PCLO | c.5503G>C p.D1835H | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100430721; called by muse, varscan2
- PCLO | c.5386G>C p.E1796Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100430728, COSV61642955; called by muse, varscan2
- PCLO | c.4858G>C p.D1620H | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100430730; called by muse, mutect2
- PDE7A | c.904C>G p.L302V (on ENST00000401827 / NM_001242318.3; = p.L276V on NM_002603.4) | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV101052649, COSV65154310; called by muse, mutect2, varscan2
- PHACTR3 | c.240G>C p.W80C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100732451; called by muse, mutect2, varscan2
- PHLDA1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.509); catalogued as rs982542267, COSV99876514; called by muse, mutect2
- PLA2G4D | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99299536; called by muse, mutect2, varscan2
- PLXNA2 | c.3208C>G p.Q1070E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV100885348; called by muse, mutect2, varscan2
- PPT2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751977544, COSV52997718; called by muse, mutect2, varscan2
- PRDM4 | c.2276C>A p.S759* | Nonsense Mutation (SNP) | VAF 21/118 reads (18%) | catalogued as COSV99946526; called by muse, mutect2, varscan2
- PRKCZ | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs375920005; called by muse, mutect2, varscan2
- PRKD2 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV99354227; called by muse, mutect2, varscan2
- PRPF40B | c.1423G>C p.E475Q (on ENST00000380281; = p.E469Q on NM_012272.3) | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV56058665, COSV99979703; called by muse, mutect2
- PSD3 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs368285479; called by muse, mutect2, varscan2
- RAI2 | c.1510A>C p.K504Q | Missense Mutation (SNP) | VAF 138/523 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518262; called by muse, mutect2, varscan2
- RALGDS | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100924384; called by muse, mutect2, varscan2
- RIOK1 | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.857); catalogued as COSV53572234, COSV99344698; called by muse, mutect2, varscan2
- RTKN | c.1666C>T p.R556C (on ENST00000272430 / NM_001015055.2; = p.R543C on NM_033046.2) | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs1253780029, COSV51961727; called by muse, mutect2, varscan2
- RTTN | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs375642538; called by muse, mutect2, varscan2
- SERBP1 | c.973C>G p.L325V (on ENST00000370995 / NM_001018067.2; = p.L304V on NM_015640.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100769084, COSV63414070; called by muse, mutect2, varscan2
- SIDT1 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1486067420, COSV99333641; called by muse, mutect2
- SIM2 | c.924G>C p.Q308H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs1295196712, COSV99293119; called by muse, mutect2, varscan2
- SLC25A19 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100237491; called by muse, mutect2, varscan2
- SLC8A1 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.609); catalogued as rs923216445, COSV100245574, COSV60486990; called by muse, mutect2
- SLTM | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV99989094; called by muse, mutect2, varscan2
- SOCS6 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV101205710; called by muse, varscan2
- SOCS6 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV101205711, COSV67546221; called by muse, varscan2
- SOCS6 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV101205712; called by muse, varscan2
- SOCS6 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV101205714; called by muse, mutect2, varscan2
- SPON1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100115643; called by muse, mutect2, varscan2
- SPTY2D1 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100311610; called by muse, mutect2, varscan2
- STEAP4 | c.1214G>C p.R405T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs546856958, COSV100112522, COSV100112534; called by muse, mutect2, varscan2
- SYK | c.1810C>T p.L604F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101002408; called by muse, mutect2, varscan2
- THSD7A | c.2505G>A p.W835* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101448646; called by muse, mutect2
- TIAM2 | c.3082G>C p.D1028H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as COSV100018639; called by muse, mutect2, varscan2
- TRIM16L | c.368-1G>C p.X123_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV101192596; called by muse, mutect2, varscan2
- TRIM21 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.215); catalogued as COSV99587645; called by muse, mutect2
- TRIM55 | c.897A>T p.K299N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99396719; called by muse, mutect2, varscan2
- TRRAP | c.7028G>A p.R2343Q (on ENST00000359863 / NM_001244580.1; = p.R2325Q on NM_003496.3) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1197218649, COSV100722335; called by muse, mutect2, varscan2
- TTLL5 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs534989089, COSV100089825; called by muse, mutect2, varscan2
- WDR17 | c.2978G>C p.G993A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV99707383; called by muse, mutect2, varscan2
- ZFAND4 | c.988C>G p.H330D | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100762949; called by muse, mutect2
- ZNF546 | c.1970G>C p.R657T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV100713412, COSV61257131; called by muse, mutect2
- ZNF74 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 32/147 reads (22%) | catalogued as COSV100677455; called by muse, mutect2, varscan2
- ZNF750 | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | catalogued as COSV99489722, COSV99489740; called by muse, mutect2, varscan2
- FAS | c.421del p.E141Nfs*46 | Frame Shift Del (DEL) | VAF 96/472 reads (20%) | called by pindel, varscan2
- RAB2A | c.629del p.G210Afs*10 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- WASF2 | c.364del p.E122Kfs*51 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- ACAD8 | c.447C>T p.L149= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55542365, COSV99844258; called by muse, mutect2, varscan2
- ARHGAP35 | c.3099G>A p.L1033= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs1159810935, COSV101350902; called by muse, mutect2, varscan2
- ATP2B3 | c.1452C>T p.T484= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as rs782621008, COSV99684041; called by muse, mutect2, varscan2
- CRB1 | c.2805C>T p.H935= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs767706271, COSV66332011, COSV66333152; called by muse, mutect2, varscan2
- CTSC | c.453C>T p.V151= | Silent (SNP) | VAF 37/161 reads (23%) | catalogued as COSV99910622; called by muse, mutect2, varscan2
- DHX16 | c.1284G>A p.K428= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100905174; called by muse, mutect2
- DNMBP | c.3213G>A p.E1071= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1327159988, COSV100143534; called by muse, mutect2, varscan2
- EGLN1 | c.594C>T p.I198= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1159134905, COSV100791255; called by muse, mutect2, varscan2
- ENO3 | c.639C>T p.F213= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs373847361, COSV52779763; called by muse, mutect2, varscan2
- GPATCH3 | c.579G>A p.G193= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100658759; called by muse, mutect2, varscan2
- KIF4B | c.411A>G p.K137= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV101469230; called by muse, mutect2, varscan2
- KRT14 | c.1170G>A p.E390= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99390972; called by muse, mutect2, varscan2
- KRT14 | c.813G>A p.E271= | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as COSV99390974; called by muse, mutect2
- MAS1 | c.957C>T p.V319= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99396872; called by muse, mutect2, varscan2
- MET | c.1062C>T p.A354= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs755166920, COSV100577159; ClinVar: likely benign; called by muse, mutect2, varscan2
- MORC4 | c.375C>T p.F125= | Silent (SNP) | VAF 40/217 reads (18%) | catalogued as COSV99717071; called by muse, mutect2, varscan2
- NLGN3 | c.1170C>G p.L390= (on ENST00000358741 / NM_181303.2; = p.L370= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100704654, COSV62443692; called by muse, mutect2, varscan2
- NOS2 | c.462C>T p.F154= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV58227046; called by muse, mutect2
- NPC1L1 | c.2427C>T p.V809= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV99205216; called by muse, mutect2, varscan2
- OR10G2 | c.885G>A p.L295= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV101606948, COSV73390307; called by muse, mutect2
- OR4B1 | c.498C>T p.F166= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV100535567; called by muse, mutect2, varscan2
- PAK5 | c.1431G>A p.V477= | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as COSV62031915; called by muse, varscan2
- PDE4DIP | c.4194G>A p.L1398= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100518517, COSV57695861; called by muse, mutect2, varscan2
- PFKL | c.564C>T p.V188= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV100827111; called by muse, mutect2, varscan2
- PPP1R16B | c.741C>T p.L247= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV55382695; called by muse, mutect2
- RIOK1 | c.729G>A p.V243= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99344700; called by muse, mutect2, varscan2
- SOCS6 | c.1260G>A p.L420= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV101205716, COSV67546162; called by muse, mutect2, varscan2
- SYNJ2BP | c.195C>A p.I65= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV56447086, COSV99832616; called by muse, mutect2, varscan2
- TPO | c.1569C>T p.F523= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100220565; called by muse, mutect2, varscan2
- TRPV1 | c.480G>A p.L160= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99439288; called by muse, mutect2, varscan2
- UBE2E2 | c.477C>T p.S159= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100232762; called by muse, mutect2, varscan2
- KIF16B | c.3498+3396C>T | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100734131; called by muse, mutect2, varscan2
- MIR1207 | n.37G>A | RNA (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- ZNF271P | n.2158G>C | RNA (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
